Somatic mutation profile of cancer-model specimen HCM-CSHL-1266-C20-85N (3D Organoid; aliquot HCM-CSHL-1266-C20-85N-01D-A882-36), derived from the metastatic tumor of HCMI case HCM-CSHL-1266-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 34.7 years (12,684 days).
Specimen HCM-CSHL-1266-C20-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55b49882-4f1b-43a8-ab0e-af8e32e95d69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-1266-C20-11A (Solid Tissue Normal), aliquot HCM-CSHL-1266-C20-11A-01D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e403d6c-5039-4a6e-9d7c-9fd433a9f8a9

The open-access MAF lists 147 somatic variants for this specimen: 107 protein-altering or splice-affecting, 37 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 37, Nonsense Mutation 9, In Frame Del 4, Frame Shift Del 3, Translation Start Site 2, Frame Shift Ins 2, Splice Region 1, 3'Flank 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 497/498 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AL592490.1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 78/538 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV69425032; called by muse, mutect2, varscan2
- ARHGEF28 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1298080364, COSV104383102; called by muse, varscan2
- ATF5 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 112/372 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as rs531308133; called by muse, mutect2, varscan2
- CACNA1B | c.4376C>T p.S1459L | Missense Mutation (SNP) | VAF 250/552 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.636); catalogued as rs775488955, COSV53149897; called by muse, mutect2, varscan2
- CLCN4 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV66466160; called by muse, mutect2, varscan2
- COL5A2 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 173/365 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs983377642, COSV66410763; called by muse, mutect2, varscan2
- CSMD3 | c.2876C>A p.S959* (on ENST00000297405 / NM_001363185.1; = p.S855* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 210/631 reads (33%) | catalogued as COSV52287772; called by muse, mutect2, varscan2
- EEF1A2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 157/1035 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs1325353717, COSV53207183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENTPD4 | c.1644C>A p.F548L | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV62268138; called by muse, mutect2, varscan2
- FAM135B | c.1682A>C p.K561T | Missense Mutation (SNP) | VAF 66/805 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as rs368544496; called by muse, mutect2
- FAT3 | c.8505A>T p.Q2835H | Missense Mutation (SNP) | VAF 300/592 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99969150; called by muse, mutect2, varscan2
- GABRA5 | c.751T>G p.F251V | Missense Mutation (SNP) | VAF 172/321 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59475409; called by muse, mutect2, varscan2
- GALNT9 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 410/410 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs1486896844; called by muse, mutect2, varscan2
- GPR158 | c.3370G>T p.A1124S | Missense Mutation (SNP) | VAF 443/444 reads (100%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as rs1047586610, COSV66267663; called by muse, mutect2, varscan2
- GRIN2C | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 89/532 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751104229; called by muse, mutect2, varscan2
- HECW1 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 276/728 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.37); catalogued as rs754513729, COSV67825760, COSV67831887; called by muse, mutect2, varscan2
- HELZ2 | c.2506G>A p.G836S (on ENST00000467148 / NM_001037335.2; = p.G267S on NM_033405.3) | Missense Mutation (SNP) | VAF 65/610 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1203692082; called by muse, mutect2, varscan2
- IGHG3 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 271/461 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as rs745813727; called by muse, mutect2, varscan2
- LATS1 | c.800C>A p.S267* | Nonsense Mutation (SNP) | VAF 308/467 reads (66%) | catalogued as COSV53588519; called by muse, mutect2, varscan2
- LRIF1 | c.2014A>G p.T672A | Missense Mutation (SNP) | VAF 542/546 reads (99%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs775682328; called by muse, mutect2, varscan2
- LRRC69 | c.325T>G p.L109V | Missense Mutation (SNP) | VAF 79/326 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1428918343; called by muse, mutect2, varscan2
- MASP1 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 158/254 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs760110023; called by muse, varscan2
- MFAP3L | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 155/155 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as rs200622205, COSV64372678; called by muse, mutect2, varscan2
- MUC16 | c.11376G>A p.M3792I | Missense Mutation (SNP) | VAF 214/409 reads (52%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs754905495; called by muse, mutect2, varscan2
- OR10C1 | c.534C>A p.F178L (on ENST00000622521; = p.F176L on NM_013941.3) | Missense Mutation (SNP) | VAF 392/822 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs1215726941, COSV65822546; called by muse, mutect2, varscan2
- PC | c.1867C>A p.P623T | Missense Mutation (SNP) | VAF 133/487 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67369447; called by muse, mutect2, varscan2
- PCDH17 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 87/540 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV100931497; called by muse, mutect2, varscan2
- PCDHGA10 | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 554/792 reads (70%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as rs746539261, COSV99540054; called by muse, mutect2, varscan2
- PDPR | c.1361G>A p.G454D | Missense Mutation (SNP) | VAF 120/424 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs957183542; called by muse, mutect2, varscan2
- PPIL2 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 62/378 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs769760032; called by muse, mutect2, varscan2
- PPP4R4 | c.2611T>A p.S871T | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.969); catalogued as rs750925625; called by mutect2, varscan2
- RBMXL3 | c.2347C>T p.R783* | Nonsense Mutation (SNP) | VAF 183/549 reads (33%) | catalogued as rs1373914939, COSV100407349; called by muse, mutect2, varscan2
- ROBO2 | c.1482T>G p.S494R | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs13060040; called by muse, mutect2, varscan2
- RYR3 | c.3298C>T p.R1100* | Nonsense Mutation (SNP) | VAF 296/542 reads (55%) | catalogued as rs1297136189; called by muse, mutect2, varscan2
- SCN1A | c.5822C>T p.T1941M (on ENST00000303395 / NM_001202435.3; = p.T1930M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/292 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.075); catalogued as rs756845310, COSV57660387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC62 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 102/320 reads (32%) | catalogued as rs141360935; called by muse, mutect2, varscan2
- SLC22A2 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 670/671 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1314319598, COSV65266636; called by muse, mutect2, varscan2
- SLC22A8 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 121/482 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as rs769079351; called by muse, mutect2, varscan2
- SLC24A5 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 231/488 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1312635224, COSV58316551; called by muse, mutect2, varscan2
- SLITRK5 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 76/762 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs144076922, COSV100280998; called by muse, mutect2, varscan2
- SRRM2 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 219/328 reads (67%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as rs745979288; called by muse, mutect2, varscan2
- SYNE1 | c.10730A>C p.Q3577P (on ENST00000367255 / NM_182961.4; = p.Q3584P on NM_033071.3) | Missense Mutation (SNP) | VAF 329/488 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs757925072; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCAF1 | c.2281C>T p.R761C | Missense Mutation (SNP) | VAF 104/275 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs775955914; called by muse, mutect2, varscan2
- TGM5 | c.1412G>T p.G471V (on ENST00000220420 / NM_201631.4; = p.G389V on NM_004245.4) | Missense Mutation (SNP) | VAF 55/350 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as COSV55008995; called by muse, mutect2, varscan2
- TIAM1 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs970048985, COSV99732887; called by muse, mutect2, varscan2
- VPS51 | c.1038C>G p.S346R | Missense Mutation (SNP) | VAF 28/625 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.05); catalogued as COSV54207232, COSV54208442; called by muse, mutect2
- WDR41 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 92/320 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs776842528, COSV53737342; called by muse, mutect2, varscan2
- ZBTB43 | c.662A>C p.D221A | Missense Mutation (SNP) | VAF 302/528 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.206); catalogued as rs771306645, COSV65094936; called by muse, varscan2
- ZC3H3 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 885/1252 reads (71%) | catalogued as rs764083420; called by muse, mutect2, varscan2
- ZC3H4 | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 101/301 reads (34%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.723); catalogued as rs1369711181; called by muse, mutect2, varscan2
- ZFYVE9 | c.3113C>G p.S1038C | Missense Mutation (SNP) | VAF 78/296 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs192873630; called by muse, mutect2, varscan2
- ZNF25 | c.176A>G p.K59R | Missense Mutation (SNP) | VAF 60/322 reads (19%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.681); catalogued as rs937732033; called by muse, mutect2, varscan2
- ZNF84 | c.781A>G p.K261E | Missense Mutation (SNP) | VAF 397/398 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs944613069; called by muse, mutect2, varscan2
- ABHD14B | c.422A>C p.K141T | Missense Mutation (SNP) | VAF 343/343 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- AJUBA | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 271/748 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- AL031777.2 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 199/406 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ALG5 | c.11_19del p.L4_L6del | In Frame Del (DEL) | VAF 142/536 reads (26%) | called by mutect2, pindel, varscan2
- ANXA8 | c.937G>A p.G313S | Missense Mutation (SNP) | VAF 371/626 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APC | c.4055_4064delinsAT p.V1352Dfs*20 | Frame Shift Del (DEL) | VAF 268/273 reads (98%) | called by pindel, varscan2*
- AQR | c.1406A>T p.N469I | Missense Mutation (SNP) | VAF 180/366 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARL14EP | c.28C>A p.Q10K | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- ART5 | c.670A>T p.I224F | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ASTN1 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 94/196 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- C2orf16 | c.3665C>T p.S1222F | Missense Mutation (SNP) | VAF 134/535 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CASZ1 | c.2843C>G p.P948R | Missense Mutation (SNP) | VAF 177/511 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- CCDC178 | c.2522A>T p.Q841L (on ENST00000383096 / NM_001105528.3; = p.Q803L on NM_198995.3) | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCDC88B | c.3469_3470delinsT p.E1157Cfs*63 | Frame Shift Del (DEL) | VAF 130/707 reads (18%) | called by pindel, varscan2*
- CPN2 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 123/423 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DGKA | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 86/328 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); called by muse, varscan2
- DPM1 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 80/540 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF4B | c.352G>T p.G118* | Nonsense Mutation (SNP) | VAF 20/184 reads (11%) | called by mutect2, varscan2
- EPB41L5 | c.1421T>G p.M474R | Missense Mutation (SNP) | VAF 234/474 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.014); called by muse, mutect2
- FAM76A | c.840C>A p.A280= | Splice Region (SNP) | VAF 52/118 reads (44%) | called by muse, mutect2, varscan2
- FUT4 | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 379/882 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- GEMIN6 | c.394del p.V132Sfs*2 | Frame Shift Del (DEL) | VAF 142/624 reads (23%) | called by mutect2, pindel, varscan2
- GLYATL3 | c.753_755del p.D252del | In Frame Del (DEL) | VAF 194/466 reads (42%) | called by mutect2, pindel, varscan2
- HOXA7 | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 276/675 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- IKZF2 | c.1369A>G p.I457V | Missense Mutation (SNP) | VAF 162/347 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRS4 | c.1384G>C p.G462R | Missense Mutation (SNP) | VAF 304/472 reads (64%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); called by muse, varscan2
- LAMC3 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 325/626 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- LRRFIP1 | c.693A>T p.Q231H (on ENST00000392000 / NM_001137552.2; = p.Q207H on NM_004735.4) | Missense Mutation (SNP) | VAF 252/518 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NOP9 | c.597_603delinsC p.D200_T201del | In Frame Del (DEL) | VAF 77/444 reads (17%) | called by pindel, varscan2*
- ODF2 | c.2485G>A p.A829T (on ENST00000434106 / NM_153433.2; = p.A805T on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 120/272 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4C12 | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 272/360 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH15 | c.5669C>A p.A1890E | Missense Mutation (SNP) | VAF 320/320 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- PITPNM2 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 539/540 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); called by muse, varscan2
- PNISR | c.1619C>G p.S540* | Nonsense Mutation (SNP) | VAF 185/301 reads (61%) | called by muse, mutect2, varscan2
- POGLUT1 | c.1115A>G p.Y372C | Missense Mutation (SNP) | VAF 93/232 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- PTBP3 | c.1069A>C p.N357H | Missense Mutation (SNP) | VAF 126/322 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIC1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 71/179 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- RSPH10B | c.1568T>A p.L523Q | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by mutect2, varscan2
- SPAG1 | c.1340G>C p.G447A | Missense Mutation (SNP) | VAF 164/1066 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, varscan2
- STEAP2 | c.1275A>C p.R425S | Missense Mutation (SNP) | VAF 70/324 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TAF1A | c.1261A>G p.I421V | Missense Mutation (SNP) | VAF 202/203 reads (100%) | SIFT tolerated (0.99); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TFPI | c.208T>C p.F70L | Missense Mutation (SNP) | VAF 173/314 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- TG | c.5888A>C p.N1963T | Missense Mutation (SNP) | VAF 19/728 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2
- TRPC4 | c.2042A>G p.K681R | Missense Mutation (SNP) | VAF 60/522 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSHZ3 | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 158/548 reads (29%) | called by muse, mutect2, varscan2
- UBR1 | c.1653G>C p.E551D | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2
- UNCX | c.1508_1510del p.A503del | In Frame Del (DEL) | VAF 79/781 reads (10%) | called by pindel, varscan2*
- USP48 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 119/329 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ZBED4 | c.1940A>C p.K647T | Missense Mutation (SNP) | VAF 241/346 reads (70%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); called by muse, varscan2
- ZNF667 | c.1128T>A p.H376Q | Missense Mutation (SNP) | VAF 26/391 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- ZNF84 | c.1701dup p.E568Rfs*5 | Frame Shift Ins (INS) | VAF 109/387 reads (28%) | called by mutect2, varscan2
- ZNF84 | c.1707dup p.P570Tfs*3 | Frame Shift Ins (INS) | VAF 114/563 reads (20%) | called by mutect2*, pindel, varscan2*
- ZNF888 | c.634A>C p.K212Q | Missense Mutation (SNP) | VAF 137/213 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ANK3 | c.3009C>T p.H1003= (on ENST00000280772 / NM_001320874.2; = p.H137= on NM_001149.3) | Silent (SNP) | VAF 471/472 reads (100%) | catalogued as rs147312170; called by muse, varscan2
- AP2A2 | c.534G>A p.T178= | Silent (SNP) | VAF 282/288 reads (98%) | catalogued as rs757988092; called by muse, mutect2, varscan2
- ATP13A4 | c.3549T>G p.S1183= | Silent (SNP) | VAF 82/243 reads (34%) | catalogued as COSV61321448; called by muse, mutect2, varscan2
- BGN | c.615C>T p.F205= | Silent (SNP) | VAF 145/359 reads (40%) | catalogued as rs935930397, COSV59036001; called by muse, mutect2, varscan2
- CCDC178 | c.6T>C p.T2= | Silent (SNP) | VAF 76/113 reads (67%) | called by muse, mutect2, varscan2
- CHSY3 | c.126C>T p.S42= | Silent (SNP) | VAF 546/547 reads (100%) | called by muse, mutect2, varscan2
- CTNNBIP1 | c.108C>T p.S36= | Silent (SNP) | VAF 128/384 reads (33%) | catalogued as rs765598833, COSV101032904; called by muse, mutect2, varscan2
- DAGLB | c.1479G>T p.G493= | Silent (SNP) | VAF 177/460 reads (38%) | called by muse, mutect2, varscan2
- ELF1 | c.573G>A p.T191= | Silent (SNP) | VAF 116/406 reads (29%) | catalogued as rs138849972; called by muse, mutect2, varscan2
- ERI2 | c.273A>G p.E91= | Silent (SNP) | VAF 182/271 reads (67%) | called by muse, mutect2, varscan2
- FBXW7 | c.1959G>A p.T653= (on ENST00000281708 / NM_001349798.2; = p.T573= on NM_018315.5) | Silent (SNP) | VAF 99/267 reads (37%) | catalogued as rs767500139, COSV55899122, COSV55917020; called by muse, mutect2, varscan2
- GABBR1 | c.504C>T p.R168= | Silent (SNP) | VAF 492/1007 reads (49%) | catalogued as rs1049475813; called by muse, mutect2, varscan2
- GAL3ST4 | c.1323T>C p.S441= | Silent (SNP) | VAF 71/455 reads (16%) | called by muse, mutect2, varscan2
- HEATR1 | c.1659G>T p.T553= | Silent (SNP) | VAF 81/184 reads (44%) | catalogued as rs775414720, COSV63983406; called by muse, mutect2, varscan2
- KCNT1 | c.2634G>A p.A878= (on ENST00000488444; = p.A897= on NM_020822.3) | Silent (SNP) | VAF 177/365 reads (48%) | catalogued as rs142642528; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- KDM6A | c.2709A>C p.L903= | Silent (SNP) | VAF 45/47 reads (96%) | called by muse, varscan2
- KLHL11 | c.1995C>T p.Y665= | Silent (SNP) | VAF 154/383 reads (40%) | called by muse, mutect2, varscan2
- LRRC23 | c.201G>A p.L67= | Silent (SNP) | VAF 31/440 reads (7%) | catalogued as rs201048353; called by muse, mutect2
- MAP7D3 | c.2406A>T p.P802= | Silent (SNP) | VAF 161/448 reads (36%) | called by muse, mutect2, varscan2
- MUC16 | c.20460A>G p.L6820= | Silent (SNP) | VAF 198/348 reads (57%) | called by muse, mutect2, varscan2
- NAALAD2 | c.573T>C p.V191= | Silent (SNP) | VAF 143/316 reads (45%) | called by muse, mutect2, varscan2
- NPAP1 | c.75C>T p.P25= | Silent (SNP) | VAF 311/661 reads (47%) | catalogued as rs776835685, COSV61508007; called by muse, mutect2, varscan2
- NUSAP1 | c.414C>T p.D138= | Silent (SNP) | VAF 178/400 reads (45%) | catalogued as rs747528263; called by muse, mutect2, varscan2
- PCDH11X | c.39G>A p.L13= | Silent (SNP) | VAF 383/384 reads (100%) | called by muse, mutect2, varscan2
- PCDHAC2 | c.1176A>G p.Q392= | Silent (SNP) | VAF 24/577 reads (4%) | called by muse, mutect2
- PPIL2 | c.1056C>T p.D352= | Silent (SNP) | VAF 98/591 reads (17%) | catalogued as rs751394220, COSV58606243; called by muse, mutect2, varscan2
- RSPH10B | c.1569G>T p.L523= | Silent (SNP) | VAF 17/136 reads (13%) | called by mutect2, varscan2
- SGSM1 | c.2649G>A p.A883= (on ENST00000400359 / NM_001039948.4; = p.A822= on NM_133454.3) | Silent (SNP) | VAF 318/593 reads (54%) | catalogued as rs770834809; called by muse, varscan2
- SHANK1 | c.93C>T p.D31= | Silent (SNP) | VAF 363/542 reads (67%) | catalogued as rs764205732, COSV99520023; called by muse, mutect2, varscan2
- SLC45A1 | c.1572C>A p.R524= | Silent (SNP) | VAF 117/434 reads (27%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.2739T>G p.P913= | Silent (SNP) | VAF 52/343 reads (15%) | called by muse, mutect2, varscan2
- TNRC6C | c.2148G>A p.P716= | Silent (SNP) | VAF 234/511 reads (46%) | catalogued as rs768647250; called by muse, mutect2, varscan2
- TRIM72 | c.1311G>A p.P437= | Silent (SNP) | VAF 296/453 reads (65%) | catalogued as rs1224431203; called by muse, mutect2, varscan2
- TSPAN13 | c.111C>T p.F37= | Silent (SNP) | VAF 85/526 reads (16%) | catalogued as rs757952595; called by muse, mutect2, varscan2
- TTN | c.21396A>G p.Q7132= (on ENST00000591111; = p.Q6205= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 124/332 reads (37%) | catalogued as COSV60190155; called by muse, mutect2, varscan2
- UBC | c.177C>T p.Y59= | Silent (SNP) | VAF 264/679 reads (39%) | catalogued as rs11537757; called by muse, mutect2, varscan2
- ZNF619 | c.894G>A p.K298= | Silent (SNP) | VAF 39/264 reads (15%) | called by muse, mutect2, varscan2
- BOLL | c.*1G>C | 3'UTR (SNP) | VAF 82/368 reads (22%) | called by muse, mutect2, varscan2
- OSCP1 | c.546+3475C>T | Intron (SNP) | VAF 50/148 reads (34%) | catalogued as rs1184541687; called by mutect2, varscan2
- PTPRU | chr1:29325739 C>T | 3'Flank (SNP) | VAF 350/546 reads (64%) | catalogued as rs765826238; called by muse, mutect2, varscan2
